Somatic mutation profile of tumor specimen TCGA-13-0899-01A (aliquot TCGA-13-0899-01A-01W-0420-08) from TCGA case TCGA-13-0899, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.3 years (22,031 days).
Specimen TCGA-13-0899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d730fdc-0507-43f5-a93a-7a973c287c5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0899-10A (Blood Derived Normal), aliquot TCGA-13-0899-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01913850-b4a1-4459-8e26-ab89fac5ba98

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Frame Shift Ins 4, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, RNA 2, 3'UTR 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B4 | c.1147dup p.H383Pfs*103 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs387907186; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 607/681 reads (89%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.8007A>T p.E2669D (on ENST00000359028; = p.E2645D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV62339203; called by muse, mutect2
- AVPR2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs782052413, COSV61686387; called by muse, mutect2, varscan2
- BAP1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV56230686; called by muse, mutect2, varscan2
- C19orf47 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 131/188 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63508468; called by muse, mutect2, varscan2
- CBX8 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53935480; called by muse, mutect2, varscan2
- CCAR1 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV56267437; called by muse, mutect2, varscan2
- CGNL1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs749365303, COSV55563801; called by muse, mutect2, varscan2
- CNOT3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1568634607, COSV99651560; called by muse, mutect2
- DHX8 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.885); catalogued as rs377681392; called by muse, mutect2, varscan2
- DTL | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100877156; called by muse, mutect2
- EFNA4 | c.560T>C p.L187S | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.986); catalogued as COSV63018037; called by muse, mutect2, varscan2
- EGR4 | c.925G>A p.A309T (on ENST00000545030; = p.A206T on NM_001965.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs781115397, COSV71531914, COSV71532162; called by muse, mutect2, varscan2
- FAM171B | c.851G>C p.S284T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV59000865; called by muse, mutect2, varscan2
- FBXO42 | c.1453dup p.R485Pfs*28 | Frame Shift Ins (INS) | VAF 13/117 reads (11%) | catalogued as rs747210971; called by mutect2, pindel
- GCNA | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 58/636 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs751159241, COSV65465923, COSV65467771; called by muse, varscan2
- H2BC5 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.16); catalogued as COSV56799921; called by muse, mutect2, varscan2
- ITGAE | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs189112267, COSV53989487; called by muse, mutect2, varscan2
- MAB21L2 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV58260866; called by muse, mutect2, varscan2
- MCTP2 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59141024; called by muse, mutect2, varscan2
- MEP1B | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52495745; called by muse, mutect2, varscan2
- NLRP3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 72/472 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60220386; called by muse, varscan2
- ORAI2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs762973215, COSV62689169; called by muse, mutect2, varscan2
- PLA2G12A | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs368449766; called by muse, mutect2, varscan2
- SCN2A | c.2427G>T p.K809N | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51832948; called by muse, mutect2, varscan2
- SLC4A5 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV61024797; called by muse, mutect2, varscan2
- SNTG1 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 49/299 reads (16%) | catalogued as COSV52426237; called by muse, mutect2, varscan2
- SON | c.3721G>A p.V1241I | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV51651200; called by muse, mutect2, varscan2
- STYXL2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs747760393, COSV54801849; called by muse, varscan2
- TET1 | c.6067G>A p.A2023T | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65382180; called by muse, mutect2, varscan2
- TNS3 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV60787008; called by muse, mutect2, varscan2
- TOPORS | c.685_686del p.Q229Vfs*15 | Frame Shift Del (DEL) | VAF 34/219 reads (16%) | catalogued as rs780487938; called by mutect2, pindel, varscan2
- UPF2 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1190196644, COSV62658467; called by muse, mutect2, varscan2
- ZNF331 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53475012; called by muse, mutect2, varscan2
- ZNF7 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57382702; called by muse, mutect2, varscan2
- AGAP6 | c.755C>T p.T252I (on ENST00000374056 / NM_001365867.1; = p.T275I on NM_001077665.2) | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FXR2 | c.1489dup p.R497Pfs*12 | Frame Shift Ins (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel, varscan2
- ISX | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 18/594 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- KIF22 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MELTF | c.1092dup p.Y365Lfs*49 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- NTHL1 | c.356_357del p.Y119* (on ENST00000219066; = p.Y111* on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- SASH3 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SDK1 | c.4168_4170del p.R1390del | In Frame Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- AC092143.1 | c.1944C>T p.A648= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs143913140; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD40 | c.336G>A p.T112= | Silent (SNP) | VAF 153/863 reads (18%) | catalogued as rs267605960, COSV64847508; called by muse, mutect2, varscan2
- DCUN1D3 | c.855G>A p.G285= | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- IGHM | c.585C>T p.F195= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- MAP3K14 | c.1983G>A p.L661= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV100766402; called by muse, mutect2
- MAPK14 | c.30G>C p.R10= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs747908432, COSV57694728; called by muse, mutect2, varscan2
- NLRC5 | c.2691G>A p.L897= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV52649606; called by muse, mutect2, varscan2
- OPRM1 | c.468C>T p.S156= | Silent (SNP) | VAF 344/684 reads (50%) | catalogued as COSV57672680; called by muse, mutect2, varscan2
- PCDHA13 | c.714C>T p.N238= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs139888237; called by muse, mutect2, varscan2
- PLTP | c.381T>G p.T127= | Silent (SNP) | VAF 56/327 reads (17%) | catalogued as COSV62463799; called by muse, mutect2, varscan2
- SHISA2 | c.876G>A p.A292= | Silent (SNP) | VAF 206/282 reads (73%) | catalogued as rs772519736, COSV60110166; called by muse, mutect2, varscan2
- THAP9 | c.984T>C p.G328= | Silent (SNP) | VAF 42/164 reads (26%) | catalogued as COSV56355703; called by muse, mutect2, varscan2
- VCAN | c.8583A>C p.P2861= | Silent (SNP) | VAF 66/311 reads (21%) | catalogued as COSV99424898; called by mutect2, varscan2
- ZFP57 | c.886A>C p.R296= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV65305671; called by muse, mutect2, varscan2
- ZNF511 | c.336C>T p.C112= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs747119853, COSV62919639; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445577 T>A | 3'Flank (SNP) | VAF 40/121 reads (33%) | called by muse, mutect2, varscan2
- GRM8 | c.727+48393C>T | Intron (SNP) | VAF 20/123 reads (16%) | catalogued as rs369466436; called by muse, mutect2, varscan2
- KIF2A | c.1647-1180C>T | Intron (SNP) | VAF 65/74 reads (88%) | catalogued as COSV66944608; called by muse, mutect2, varscan2
- UVSSA | c.*9369G>A | 3'UTR (SNP) | VAF 19/70 reads (27%) | catalogued as rs527832969, COSV61347455; called by muse, varscan2
- XIST | n.7945T>C | RNA (SNP) | VAF 10/188 reads (5%) | catalogued as rs1465527595; called by muse, mutect2
- XIST | n.7943C>T | RNA (SNP) | VAF 12/188 reads (6%) | catalogued as rs1213079190; called by muse, mutect2
